Gene-level copy-number profile of tumor specimen C3L-01202-54 from CPTAC case C3L-01202, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 65.4 years (23,871 days).
Specimen C3L-01202-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bdfda964-3f6a-49b0-890b-2db0ab95049d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01202-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/2f428343-feb0-4a25-81f3-eeeaaa71b33a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 111; copy number 2: 55,593; copy number 3: 2,647.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,072,767–40,806,344, 49 genes: CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2, ANKRD20A2P, BX664727.3, RNU6-1269P, BX664727.2, SNX18P8, FAM95B1, BX664727.1, CNN2P2, GXYLT1P3, AL591471.1, AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2, AL353626.3, RNU6-156P, AL353626.1.
- chr17:75,406,069–75,406,162, 1 gene: MIR3678.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 111. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
